Gene-level copy-number profile of tumor specimen TCGA-BP-4761-01A from TCGA case TCGA-BP-4761, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 57.5 years (21,019 days).
Specimen TCGA-BP-4761-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.2d457722-539a-41ad-abd8-dd39e5e5022e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BP-4761-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/db70f7d9-9584-4132-b55a-60b449743a68

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 15,327; copy number 2: 36,682; copy number 3: 7,059; copy number 4: 739.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-BP-4761-01): tumor purity 0.65, ploidy 1.91, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:38,845,764–39,052,157, 1 gene (within-gene range 0–1): SCN11A.
- chr8:18,864,681–19,000,952, 3 genes (within-gene range 0–2): AC087821.1, SNORA62, AC009884.1.
- chr9:21,967,752–21,995,301, 1 gene (within-gene range 0–1): CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr18:36,829,106–37,232,172, 2 genes (within-gene range 0–1): KIAA1328, AC016493.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 12,946. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
